Somatic mutation profile of tumor specimen TCGA-IQ-A61I-01A (aliquot TCGA-IQ-A61I-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61I, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.1 years (23,035 days).
Specimen TCGA-IQ-A61I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d85c04e-bcf8-48b9-b683-430001c3e6b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61I-10A (Blood Derived Normal), aliquot TCGA-IQ-A61I-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a1beac-89f8-4c1c-80d5-c70b0954e91a

The open-access MAF lists 134 somatic variants for this specimen: 97 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 35, Nonsense Mutation 7, Splice Site 2, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAR2 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV100299184; called by muse, mutect2, varscan2
- ADAM19 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99976532; called by muse, mutect2, varscan2
- AGTPBP1 | c.1084G>T p.E362* (on ENST00000357081 / NM_001330701.2; = p.E322* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100429456; called by muse, varscan2
- AGTR1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767462753, COSV100836971; called by muse, mutect2, varscan2
- AHDC1 | c.3989C>A p.S1330* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99899048; called by muse, mutect2, varscan2
- ANKZF1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.592); catalogued as COSV99850359; called by muse, mutect2, varscan2
- ARAP2 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs145147471; called by muse, mutect2, varscan2
- ASTN2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs773241747, COSV100525590, COSV57798898; called by muse, mutect2, varscan2
- B4GALT3 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100157662; called by muse, mutect2, varscan2
- BAMBI | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs111458570; called by muse, mutect2, varscan2
- BBS5 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV99751719; called by muse, mutect2, varscan2
- CD34 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100178242, COSV60413996; called by muse, mutect2, varscan2
- CEP76 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100042650; called by muse, mutect2, varscan2
- CFAP58 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100458816; called by muse, mutect2, varscan2
- CHAT | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as COSV100339932; called by muse, mutect2
- CINP | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV99392110; called by muse, mutect2, varscan2
- CKLF | c.370G>A p.D124N (on ENST00000264001 / NM_016951.4; = p.D39N on NM_016326.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372025298; called by muse, mutect2
- CPT2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99598084; called by muse, mutect2, varscan2
- CYP51A1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs200921006; called by muse, mutect2, varscan2
- DGCR8 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100707863, COSV61227877; called by muse, mutect2, varscan2
- DMD | c.9436G>A p.D3146N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV100626379; called by muse, mutect2, varscan2
- DYSF | c.4366G>A p.V1456M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs763181772, COSV99245362; called by muse, mutect2, varscan2
- EIF4G2 | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.787); catalogued as COSV100379450; called by muse, mutect2, varscan2
- EWSR1 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100131080; called by muse, mutect2, varscan2
- FAM161A | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192691248, COSV100281189; called by muse, mutect2, varscan2
- FBXO40 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201011500; called by muse, mutect2, varscan2
- FCGR2A | c.641C>T p.S214L (on ENST00000271450 / NM_001136219.3; = p.S213L on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs774749223, COSV99615102; called by muse, mutect2, varscan2
- FIP1L1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184291; called by muse, mutect2, varscan2
- FLOT2 | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV101204753; called by muse, mutect2
- FRAS1 | c.5841C>G p.I1947M | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV99349627; called by muse, mutect2
- GDF10 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535252557; called by muse, varscan2
- GEMIN5 | c.4267G>A p.E1423K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1378119908, COSV53558955; called by muse, mutect2, varscan2
- HSPA6 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV59059682; called by muse, mutect2, varscan2
- ITPRID1 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV100085949; called by muse, mutect2
- KCNV2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs765751812, COSV101172541; called by muse, mutect2, varscan2
- KIAA0930 | c.971C>T p.S324L (on ENST00000336156 / NM_001009880.2; = p.S329L on NM_015264.2) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV52663577; called by muse, mutect2, varscan2
- KIAA1549L | c.1363G>A p.D455N (on ENST00000321505; = p.D752N on NM_012194.3) | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs61736871, COSV99682917; called by muse, mutect2, varscan2
- KIF26B | c.2924C>G p.S975C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100831855; called by muse, mutect2, varscan2
- MAGEE2 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV100973027; called by muse, mutect2, varscan2
- MAP3K19 | c.2394G>C p.Q798H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV100208248; called by muse, mutect2, varscan2
- MBP | c.886C>T p.R296C (on ENST00000355994 / NM_001025101.2; = p.R178C on NM_002385.3) | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1367368915, COSV62828610; called by muse, mutect2, varscan2
- MED14 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100247390; called by muse, mutect2, varscan2
- MFSD9 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV51494703, COSV99301983; called by muse, mutect2, varscan2
- MMEL1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); catalogued as rs754099706, COSV56522066; called by muse, mutect2, varscan2
- MUC16 | c.4225G>C p.E1409Q | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.331); catalogued as COSV67456004; called by muse, mutect2, varscan2
- NAALADL1 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100100898; called by muse, mutect2, varscan2
- NCR1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.331); catalogued as rs771914760, COSV52555600; called by muse, mutect2, varscan2
- NDST3 | c.1748G>A p.R583K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1442671306, COSV56613899, COSV99629956; called by muse, mutect2, varscan2
- NRAP | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100748344, COSV63489937; called by muse, mutect2, varscan2
- NUCB1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV99617773; called by muse, mutect2
- NUP205 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as COSV99606638; called by muse, mutect2, varscan2
- OR10A5 | c.716T>C p.F239S | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100203394; called by muse, mutect2
- OR1F1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100484388; called by muse, mutect2, varscan2
- OR2M3 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV101513407, COSV99081719; called by muse, mutect2, varscan2
- OR2T12 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV100527626, COSV58779477; called by muse, mutect2, varscan2
- OR4C13 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101634151, COSV73648735; called by muse, mutect2, varscan2
- PCDHA5 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV100972179; called by muse, mutect2, varscan2
- PCDHB8 | c.2180C>G p.S727* | Nonsense Mutation (SNP) | VAF 8/223 reads (4%) | catalogued as COSV99176386, COSV99176917; called by muse, mutect2
- PHF19 | c.529T>G p.S177A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100384295; called by muse, mutect2, varscan2
- PRRC2B | c.4017G>T p.W1339C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100621602; called by muse, mutect2, varscan2
- PRSS58 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 23/84 reads (27%) | catalogued as rs766468973, COSV73488547; called by muse, mutect2, varscan2
- QSER1 | c.3694G>A p.D1232N (on ENST00000399302; = p.D1361N on NM_001076786.3) | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101234718; called by muse, mutect2
- RBM27 | c.2344C>G p.P782A | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1446723774, COSV54590312; called by muse, mutect2, varscan2
- RELB | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99672797; called by muse, mutect2, varscan2
- RIBC1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs781908927, COSV99394899; called by muse, mutect2, varscan2
- SDR9C7 | c.744C>G p.N248K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99524556; called by muse, mutect2, varscan2
- SLC14A2 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675249; called by muse, mutect2, varscan2
- SOWAHB | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100530648; called by muse, mutect2, varscan2
- SPG11 | c.2971C>G p.Q991E | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV56003516, COSV99968262; called by muse, mutect2
- SPTAN1 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100823359; called by muse, mutect2, varscan2
- SREBF1 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99888531; called by muse, mutect2, varscan2
- STAT3 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.181); catalogued as COSV99232579; called by muse, mutect2, varscan2
- TERF2 | c.810C>A p.H270Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV99651361; called by muse, mutect2, varscan2
- TMC4 | c.350C>G p.S117C (on ENST00000617472 / NM_001145303.3; = p.S111C on NM_144686.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV99824678; called by muse, mutect2, varscan2
- TMEM117 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99862108, COSV99863693; called by muse, mutect2, varscan2
- TMOD1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs751262566, COSV99403790; called by muse, mutect2
- TNFRSF1B | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1180231743, COSV100884136; called by muse, mutect2, varscan2
- TOLLIP | c.367-1G>A p.X123_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99719466; called by muse, mutect2, varscan2
- TRAF2 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV56037623, COSV99916667; called by muse, mutect2, varscan2
- TRIOBP | c.2608C>G p.Q870E | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV100730742; called by muse, mutect2
- TTC3 | c.5443C>G p.L1815V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs140969268; called by muse, mutect2, varscan2
- TYK2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs747608147, COSV99314452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UPK3B | c.415C>G p.Q139E (on ENST00000257632; = p.Q84E on NM_001347684.2) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.013); catalogued as COSV99991011; called by muse, mutect2
- USP1 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100375077; called by muse, mutect2, varscan2
- USP7 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.355); catalogued as COSV100784069; called by muse, mutect2, varscan2
- UTP20 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 47/158 reads (30%) | catalogued as COSV99881086; called by muse, mutect2, varscan2
- XRRA1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100369763, COSV58500933; called by muse, mutect2, varscan2
- ZBTB44 | c.104T>A p.I35N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100777246; called by muse, mutect2, varscan2
- ZC3H7A | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV63269656, COSV63271771; called by muse, mutect2, varscan2
- ZNF211 | c.1003C>T p.H335Y (on ENST00000347302 / NM_198855.4; = p.H348Y on NM_006385.5) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99560140; called by muse, mutect2, varscan2
- ZNF324 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767990501, COSV99543172; called by muse, mutect2, varscan2
- ZNF397 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV99734755; called by muse, mutect2, varscan2
- ZNF44 | c.279G>A p.M93I (on ENST00000356109 / NM_001164276.2; = p.M45I on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV100633510; called by muse, mutect2
- ZNF561 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV100254384; called by muse, mutect2, varscan2
- ZRANB2 | c.111G>A p.E37= | Splice Region (SNP) | VAF 24/85 reads (28%) | catalogued as COSV54671343, COSV99639125; called by muse, mutect2, varscan2
- CYB5R4 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- PIK3C2B | c.497G>C p.W166S | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.224); called by muse, mutect2
- ANKMY1 | c.144C>T p.F48= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV56039093; called by muse, mutect2, varscan2
- ATP2C2 | c.249G>A p.T83= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1197418633, COSV99297650; called by muse, mutect2
- CABP5 | c.216C>T p.L72= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs757439989, COSV53152390; called by muse, mutect2
- CBX7 | c.453C>G p.L151= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99333988; called by muse, mutect2
- COL4A6 | c.5013G>A p.T1671= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs758181213, COSV100563670; called by muse, varscan2
- CSMD1 | c.8211C>T p.I2737= (on ENST00000520002; = p.I2736= on NM_033225.6) | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100145440; called by muse, mutect2
- CXorf21 | c.585G>A p.E195= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as COSV100973244; called by muse, mutect2, varscan2
- DHRS11 | c.195C>T p.I65= | Silent (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- EIF4G2 | c.2019C>T p.L673= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100379447, COSV60597026; called by muse, mutect2, varscan2
- EXPH5 | c.5490G>C p.L1830= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV56207878; called by muse, mutect2
- FMNL1 | c.831G>A p.A277= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as rs373201342, COSV58955199; called by muse, mutect2, varscan2
- FMOD | c.534G>C p.L178= | Silent (SNP) | VAF 119/205 reads (58%) | catalogued as rs766694592, COSV100724513, COSV61609907; called by muse, mutect2, varscan2
- GPC1 | c.1251C>T p.N417= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs372989599; called by muse, mutect2, varscan2
- KAT7 | c.1110C>T p.F370= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52015703, COSV99371660; called by muse, mutect2, varscan2
- KIAA1217 | c.4755C>T p.L1585= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV100286328; called by muse, mutect2, varscan2
- KIAA2026 | c.2400G>A p.R800= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV101198915; called by muse, mutect2, varscan2
- KRT7 | c.1077C>T p.A359= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs138875857; called by muse, mutect2, varscan2
- KRT8 | c.777C>T p.I259= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV53176228; called by muse, mutect2, varscan2
- MAST2 | c.2623C>T p.L875= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs12757963, COSV100787948; called by muse, mutect2, varscan2
- NECTIN4 | c.1281C>T p.L427= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100919848, COSV63513174; called by muse, mutect2, varscan2
- NLRP1 | c.1017G>A p.G339= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV99333377; called by muse, mutect2, varscan2
- NPHP4 | c.3723C>T p.V1241= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs375485412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP50 | c.516G>A p.V172= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV100754287; called by muse, mutect2, varscan2
- OR56A1 | c.762C>T p.F254= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs756307469, COSV100360418; called by muse, mutect2, varscan2
- SCNN1A | c.693G>A p.Q231= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV99964588; called by muse, mutect2, varscan2
- SCRIB | c.3480G>A p.V1160= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100252809; called by muse, mutect2, varscan2
- SLC27A6 | c.705G>A p.V235= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV99322409; called by muse, mutect2, varscan2
- SPTAN1 | c.979C>T p.L327= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs587784442, COSV100823360; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- STRC | c.4236G>A p.E1412= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100294487; called by mutect2, varscan2
- TAS1R2 | c.2283C>T p.F761= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100946168; called by muse, mutect2, varscan2
- TLR1 | c.1341C>T p.I447= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV100458371; called by muse, mutect2, varscan2
- TP53BP1 | c.1146A>G p.T382= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99780074; called by muse, mutect2, varscan2
- TRIM29 | c.345G>A p.K115= | Silent (SNP) | VAF 28/326 reads (9%) | catalogued as COSV100531576, COSV59279760; called by muse, mutect2
- TRIOBP | c.2817C>T p.L939= | Silent (SNP) | VAF 52/215 reads (24%) | catalogued as COSV60377015; called by muse, mutect2, varscan2
- ZNF287 | c.1608T>C p.Y536= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV101209347; called by muse, mutect2, varscan2
- KIF1B | c.2115+7016G>A | Intron (SNP) | VAF 13/289 reads (4%) | catalogued as COSV99822811; called by muse, mutect2
- SNORD115-14 | n.14G>A | RNA (SNP) | VAF 15/319 reads (5%) | called by muse, mutect2
